Gene-level copy-number profile of tumor specimen TCGA-06-A5U1-01A from TCGA case TCGA-06-A5U1, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 78.2 years (28,545 days).
Specimen TCGA-06-A5U1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7e29d71a-059d-466d-9299-049013151936.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-A5U1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1460b7c-45d9-417e-9dc1-fe21610632f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 12,933; copy number 2: 41,958; copy number 3: 4,894.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-A5U1-01A-11D-A33S-01): tumor purity 0.66, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:124,080,023–124,901,418, 13 genes (within-gene range 0–1): KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK.
- chr6:162,727,132–163,315,492, 6 genes (within-gene range 0–1): PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr15:96,756,987–96,842,384, 4 genes: FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,933. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
